Somatic mutation profile of tumor specimen ALCH-B0CW-TTP1-A (aliquot ALCH-B0CW-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0CW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.1 years (25,595 days).
Specimen ALCH-B0CW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d79ad3f7-a5c3-4d45-8a54-011a0371d941.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0CW-NB1-A (Blood Derived Normal), aliquot ALCH-B0CW-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7209593-505f-4635-a267-8abd5c4ab052

The open-access MAF lists 408 somatic variants for this specimen: 283 protein-altering or splice-affecting, 84 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 253, Silent 84, Intron 20, Nonsense Mutation 15, RNA 10, Splice Site 6, 5'UTR 5, Splice Region 4, Frame Shift Del 3, 3'Flank 3, 3'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.782+1G>T p.X261_splice | Splice Site (SNP) | VAF 21/159 reads (13%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.458G>T p.S153I | Missense Mutation (SNP) | VAF 43/403 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.148); catalogued as rs142435175, COSV51400032; called by muse, mutect2
- ADGRA1 | c.675G>T p.E225D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV66924914; called by muse, mutect2, varscan2
- AGXT2 | c.1451C>G p.A484G | Missense Mutation (SNP) | VAF 46/635 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as COSV99183720; called by muse, mutect2
- AIDA | c.851G>T p.R284I | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60514769; called by muse, mutect2, varscan2
- AMER3 | c.1238C>A p.P413Q | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100366408; called by muse, mutect2
- ANKS6 | c.2518G>T p.E840* | Nonsense Mutation (SNP) | VAF 25/270 reads (9%) | catalogued as COSV62052120; called by muse, mutect2
- AR | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as rs1311960941; called by muse, varscan2
- ARMCX5-GPRASP2 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV100771768; called by muse, mutect2, varscan2
- BAHD1 | c.2033G>T p.R678L | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69084436; called by muse, mutect2, varscan2
- BBS5 | c.901-1G>C p.X301_splice | Splice Site (SNP) | VAF 18/222 reads (8%) | catalogued as COSV54753160; called by muse, mutect2
- C1QTNF3 | c.167dup p.G57Wfs*24 | Frame Shift Ins (INS) | VAF 32/328 reads (10%) | catalogued as rs761303952; called by mutect2, pindel
- C2orf16 | c.3438C>G p.I1146M | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62677074; called by muse, mutect2
- C6 | c.2204G>T p.G735V | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1185381042; called by muse, mutect2, varscan2
- CACNA1I | c.776C>A p.P259Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60820046; called by muse, mutect2
- CAMKV | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as COSV56555054; called by muse, mutect2, varscan2
- CFAP221 | c.1954T>C p.Y652H | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as rs1222323481; called by muse, mutect2
- CFAP47 | c.4323G>T p.K1441N | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.588); catalogued as COSV57976619; called by muse, mutect2
- CGN | c.174G>C p.Q58H | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54974006; called by muse, mutect2, varscan2
- COL24A1 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 30/414 reads (7%) | catalogued as COSV65304236; called by muse, mutect2
- CSMD1 | c.5603C>A p.P1868H (on ENST00000520002; = p.P1867H on NM_033225.6) | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59324253; called by muse, mutect2, varscan2
- CSMD3 | c.2380G>T p.A794S (on ENST00000297405 / NM_001363185.1; = p.A690S on NM_052900.3) | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.999); catalogued as COSV52253128; called by muse, mutect2
- CUBN | c.6650G>T p.C2217F | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761858666; called by muse, mutect2
- CWF19L1 | c.1595A>G p.Y532C | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs568191434; called by muse, mutect2, varscan2
- CYLC1 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 33/319 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.089); catalogued as COSV61410564; called by muse, mutect2, varscan2
- DCAF4L2 | c.797G>C p.C266S | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV100150914; called by muse, mutect2, varscan2
- DNAH10 | c.1258G>C p.V420L (on ENST00000409039; = p.V359L on NM_207437.3) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.161); catalogued as COSV68990676; called by mutect2, varscan2
- DNAH5 | c.4767G>C p.L1589F | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369253705; called by muse, mutect2
- EDARADD | c.419G>A p.R140K (on ENST00000334232 / NM_145861.4; = p.R130K on NM_080738.4) | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.526); catalogued as COSV62061177; called by muse, mutect2, varscan2
- EEPD1 | c.1576G>T p.G526W | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54199205; called by muse, mutect2, varscan2
- EVI5 | c.1351T>C p.C451R | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as rs1451430081; called by muse, mutect2, varscan2
- FAM83H | c.1775G>A p.G592D | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.037); catalogued as rs1554622795; called by muse, mutect2
- FAT4 | c.12860G>T p.G4287V | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58685287; called by muse, mutect2
- FBXL4 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 29/439 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV57750243; called by muse, mutect2
- FGB | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); catalogued as rs769395119; called by muse, mutect2
- FLG2 | c.6047C>A p.T2016K | Missense Mutation (SNP) | VAF 42/425 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as COSV66167090; called by muse, mutect2, varscan2
- FREM1 | c.5707C>A p.L1903I | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV66530632; called by muse, mutect2, varscan2
- GAS7 | c.195G>C p.M65I (on ENST00000432992 / NM_201433.2; = p.M5I on NM_201432.2) | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.077); catalogued as COSV60445657; called by muse, mutect2
- GIGYF2 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1297435659, COSV65250074; called by muse, mutect2
- GPR101 | c.1041C>A p.D347E | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as COSV99981300; called by muse, mutect2, varscan2
- HPS4 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 54/571 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs1284255788; called by muse, mutect2
- HTR3A | c.148C>A p.R50S | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55468621; called by muse, mutect2, varscan2
- IGLON5 | c.846C>A p.S282R | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV54539462; called by muse, mutect2
- ITGAE | c.35-1G>T p.X12_splice | Splice Site (SNP) | VAF 11/42 reads (26%) | catalogued as rs1465073070; called by muse, mutect2, varscan2
- ITGAX | c.2612G>A p.R871H | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs141139311, COSV99191680; called by muse, mutect2, varscan2
- KCNA6 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1161169624; called by muse, mutect2, varscan2
- KCNJ1 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs760450195, COSV60662380; called by muse, mutect2
- KIT | c.1360G>C p.V454L | Missense Mutation (SNP) | VAF 61/658 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1560415938; ClinVar: uncertain significance; called by muse, mutect2
- KLHL33 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746483667; called by muse, mutect2, varscan2
- LATS1 | c.691G>T p.G231* | Nonsense Mutation (SNP) | VAF 18/168 reads (11%) | catalogued as COSV53596224; called by mutect2, varscan2
- LMTK3 | c.511G>T p.G171W | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV99540778; called by muse, mutect2, varscan2
- LRP1B | c.5401G>A p.G1801R | Missense Mutation (SNP) | VAF 43/436 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV67244521; called by muse, mutect2
- MFSD2A | c.574C>T p.R192W (on ENST00000372809 / NM_001136493.3; = p.R179W on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1337554400; called by muse, mutect2
- MS4A7 | c.93C>A p.Y31* | Nonsense Mutation (SNP) | VAF 26/314 reads (8%) | catalogued as rs1388137350; called by muse, mutect2
- NACC1 | c.93C>A p.D31E | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52834443; called by muse, mutect2, varscan2
- NOS3 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1417289111, COSV52488519; called by muse, mutect2, varscan2
- NSUN2 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV52953344; called by muse, mutect2
- NUP205 | c.4048G>A p.V1350I | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.106); catalogued as rs760131208; called by muse, mutect2
- NXPE1 | c.700C>A p.L234M (on ENST00000424269; = p.L92M on NM_152315.5) | Missense Mutation (SNP) | VAF 43/427 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as COSV52629630; called by muse, mutect2, varscan2
- OR10D3 | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 30/353 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs568213379; called by muse, mutect2
- OR10J3 | c.613G>T p.V205F | Missense Mutation (SNP) | VAF 58/611 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs759745047, COSV59955653; called by muse, mutect2
- OR14C36 | c.362A>T p.Y121F | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV58601916; called by muse, mutect2, varscan2
- OR1S1 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 31/366 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs1350529099, COSV58705974; called by muse, mutect2
- OR5H15 | c.446A>T p.Y149F | Missense Mutation (SNP) | VAF 26/327 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs536468006; called by muse, mutect2
- PCDHB9 | c.872C>A p.T291K | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as rs547608474; called by muse, mutect2, varscan2
- PKHD1L1 | c.560G>T p.R187M | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101006118, COSV65743536; called by muse, mutect2, varscan2
- POLDIP2 | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs963234944; called by muse, mutect2, varscan2
- POTEE | c.628C>A p.L210M | Missense Mutation (SNP) | VAF 40/432 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV100389252; called by muse, mutect2, varscan2
- POTEM | c.384C>G p.F128L | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as COSV101304492; called by muse, varscan2
- PPP3CA | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV59923955; called by muse, mutect2
- PRAMEF12 | c.1012C>A p.P338T | Missense Mutation (SNP) | VAF 25/258 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.249); catalogued as rs758354517; called by muse, mutect2
- PRTG | c.1181A>T p.Q394L | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66839753; called by muse, mutect2, varscan2
- PTDSS1 | c.964G>T p.G322C | Missense Mutation (SNP) | VAF 34/389 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as COSV61266308; called by muse, mutect2
- PTPRB | c.3674C>A p.T1225K | Missense Mutation (SNP) | VAF 60/691 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.094); catalogued as COSV54238449, COSV99717361; called by muse, mutect2
- RAD54B | c.2722A>G p.T908A | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1373718125; called by muse, mutect2
- RNF103 | c.1918G>T p.G640C | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52896339; called by muse, mutect2
- RP1 | c.5942T>C p.I1981T | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs866049923; called by muse, mutect2, varscan2
- RTL9 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.007); catalogued as rs777670576; called by muse, mutect2, varscan2
- SEPTIN11 | c.54G>T p.L18F | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV53580167; called by muse, mutect2
- SLC1A3 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 60/580 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV54319787; called by muse, mutect2
- SLC37A4 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 45/292 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.281); catalogued as rs1555191401; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNJ2 | c.2567G>C p.R856T | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62900848; called by muse, mutect2, varscan2
- THBS2 | c.1718C>A p.S573* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as COSV64681644; called by muse, mutect2, varscan2
- TLR10 | c.1987A>G p.I663V | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as COSV104395297; called by muse, mutect2, varscan2
- TRPC7 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61453734; called by muse, mutect2, varscan2
- TTC34 | c.1748A>T p.H583L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs1234250703; called by muse, mutect2
- UAP1 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs200309830; called by muse, mutect2, varscan2
- UBOX5 | c.1513G>C p.G505R | Missense Mutation (SNP) | VAF 61/467 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV53906432; called by muse, mutect2, varscan2
- UMOD | c.155G>C p.C52S | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM148555; called by muse, mutect2
- UTRN | c.5797G>C p.D1933H | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV62337479; called by muse, mutect2
- WIPF2 | c.751C>G p.P251A | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV60272010, COSV60273406; called by muse, mutect2
- ZAR1 | c.116G>T p.S39I | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs754961018; called by muse, mutect2, varscan2
- ZCCHC12 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs770459820; called by muse, mutect2, varscan2
- ZFP28 | c.2279G>C p.S760T | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV56735648; called by muse, mutect2, varscan2
- ZNF727 | c.803G>T p.C268F | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV70701541; called by muse, mutect2
- A2M | c.1093T>G p.F365V | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.188); called by muse, mutect2
- ABCC8 | c.4485C>A p.F1495L | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AC009093.9 | n.543A>T | Splice Region (SNP) | VAF 34/564 reads (6%) | called by muse, mutect2
- ACOXL | c.897C>G p.F299L | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2
- ADAM23 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRA1 | c.66C>A p.H22Q | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.767); called by muse, mutect2
- ADGRL3 | c.2326G>T p.G776* (on ENST00000506720 / NM_001322402.2; = p.G708* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 11/290 reads (4%) | called by muse, mutect2
- AKAP4 | c.1587A>T p.K529N | Missense Mutation (SNP) | VAF 40/466 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.918); called by muse, mutect2
- AL669918.1 | c.1960G>T p.G654C | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); called by muse, mutect2
- ALPK1 | c.622G>T p.G208W | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALX4 | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.383); called by muse, mutect2
- ANKRD13C | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ANKRD34C | c.1186C>T p.L396F | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.029); called by muse, mutect2
- ARNT | c.2281-2A>G p.X761_splice | Splice Site (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- ATOH1 | c.98C>A p.P33Q | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- ATP1A4 | c.2621C>A p.T874N | Missense Mutation (SNP) | VAF 20/249 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.471); called by muse, mutect2
- ATP8A1 | c.2420G>C p.S807T | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2
- ATR | c.5617G>A p.G1873S | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2
- ATRX | c.6583G>C p.V2195L | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2
- AUTS2 | c.1535C>A p.A512D | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BCAT1 | c.577T>A p.Y193N | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRCA2 | c.5258C>A p.S1753Y | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- BRWD3 | c.3511G>A p.D1171N | Missense Mutation (SNP) | VAF 42/351 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- BSN | c.3020A>G p.D1007G | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- C3orf33 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CAPN6 | c.1373T>C p.L458P | Missense Mutation (SNP) | VAF 69/552 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CASZ1 | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCNT2 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- CD33 | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, varscan2
- CEL | c.616G>T p.G206W (on ENST00000673714; = p.G203W on NM_001807.6) | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP164 | c.1277T>G p.V426G | Missense Mutation (SNP) | VAF 20/263 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- CFAP45 | c.154A>C p.S52R | Missense Mutation (SNP) | VAF 37/266 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- CHD6 | c.1532C>G p.P511R | Missense Mutation (SNP) | VAF 45/506 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CILK1 | c.931del p.A311Qfs*75 (on ENST00000350082 / NM_001375397.1; = p.A311Qfs*87 on NM_014920.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 48/388 reads (12%) | called by mutect2, pindel, varscan2
- CLASP1 | c.3370C>G p.P1124A | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLEC4F | c.409G>T p.V137L | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- CNST | c.584A>G p.Q195R | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL12A1 | c.5726A>T p.Y1909F | Missense Mutation (SNP) | VAF 21/295 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL22A1 | c.3808G>T p.G1270C | Missense Mutation (SNP) | VAF 23/255 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL4A3 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.219); called by muse, mutect2
- COL6A6 | c.2689C>A p.H897N | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.014); called by muse, mutect2
- CPED1 | c.2744A>G p.K915R | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.9); called by muse, mutect2
- CR1 | c.3375G>T p.W1125C | Missense Mutation (SNP) | VAF 61/587 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CSMD1 | c.6560T>A p.I2187N (on ENST00000520002; = p.I2186N on NM_033225.6) | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CUBN | c.8795T>C p.I2932T | Missense Mutation (SNP) | VAF 65/571 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CWC22 | c.1582A>T p.I528L | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.604); called by muse, mutect2
- DBR1 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 48/548 reads (9%) | called by muse, mutect2
- DCAF12L2 | c.1313G>T p.W438L | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DDX60 | c.5053G>C p.E1685Q | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- DEPDC7 | c.544C>G p.P182A (on ENST00000241051 / NM_001077242.2; = p.P173A on NM_139160.2) | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMRTA2 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DNAH5 | c.6687G>C p.Q2229H | Missense Mutation (SNP) | VAF 52/640 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2
- DNAJC16 | c.716G>T p.R239L | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.205); called by muse, mutect2
- EGLN1 | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMB | c.613G>C p.V205L | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.03); called by mutect2, varscan2
- EYS | c.8374G>C p.E2792Q (on ENST00000370621 / NM_001292009.1; = p.E2771Q on NM_001142800.2) | Missense Mutation (SNP) | VAF 33/297 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- EYS | c.5212C>A p.H1738N | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- EYS | c.3114C>A p.H1038Q | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); called by muse, mutect2
- FAM214A | c.2161A>G p.N721D | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FAM71B | c.1385A>T p.Q462L | Missense Mutation (SNP) | VAF 38/312 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.104); called by muse, varscan2
- FAM98A | c.1339A>G p.R447G | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT4 | c.12944G>C p.G4315A | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- FBLN2 | c.2072A>T p.Q691L | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- FBXL4 | c.1265T>A p.I422N | Missense Mutation (SNP) | VAF 29/456 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- FLNC | c.1402G>A p.V468M | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- FOXB2 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 54/346 reads (16%) | called by muse, mutect2, varscan2
- FOXJ2 | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- FRMD1 | c.1297C>A p.P433T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.055); called by muse, varscan2
- FSIP2 | c.1804C>G p.P602A | Missense Mutation (SNP) | VAF 17/424 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.121); called by muse, mutect2
- GBP7 | c.1637G>C p.R546T | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, varscan2
- GLI2 | c.2103G>T p.Q701H (on ENST00000361492 / NM_001374353.1; = p.Q718H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2
- GPR78 | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- GRAMD1C | c.1650G>T p.M550I | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- GRIA3 | c.1346A>C p.E449A | Missense Mutation (SNP) | VAF 40/344 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- GRIP1 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 40/357 reads (11%) | called by muse, mutect2, varscan2
- HEY1 | c.682G>C p.A228P | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HLTF | c.1470G>T p.W490C | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPU | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 48/363 reads (13%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- HOXD12 | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- HTR1E | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV2-26 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- IZUMO3 | c.134C>G p.P45R | Missense Mutation (SNP) | VAF 71/593 reads (12%) | SIFT tolerated (0.08); called by muse, mutect2, varscan2
- JAKMIP2 | c.540G>T p.K180N | Missense Mutation (SNP) | VAF 43/339 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- JCAD | c.2306T>C p.L769S | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNB2 | c.890G>A p.R297K | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2
- KCNV1 | c.874G>T p.V292L | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.69); called by muse, mutect2
- KHK | c.763G>T p.G255* | Nonsense Mutation (SNP) | VAF 38/347 reads (11%) | called by muse, mutect2, varscan2
- KIAA0100 | c.381G>T p.L127F | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- KIF4B | c.1209T>G p.S403R | Missense Mutation (SNP) | VAF 63/514 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- KLHL1 | c.2218G>T p.A740S | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.715); called by muse, mutect2
- KMT2D | c.7586del p.G2529Afs*14 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | called by mutect2, varscan2
- LCE1A | c.32A>T p.Q11L | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- LILRB5 | c.1351C>A p.Q451K (on ENST00000449561 / NM_001081442.3; = p.Q450K on NM_006840.5) | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LRRIQ3 | c.1288C>A p.Q430K | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.056); called by muse, mutect2
- LRTM2 | c.936C>G p.I312M | Missense Mutation (SNP) | VAF 15/251 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- LYPD8 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 54/432 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEE1 | c.485C>G p.T162S | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.054); called by muse, mutect2
- MAGI1 | c.2333C>A p.P778Q | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.367); called by muse, mutect2
- MCF2 | c.2335T>C p.W779R | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.278); called by muse, mutect2
- MEF2C | c.1109C>G p.T370S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0.001); called by muse, mutect2
- MEP1B | c.2099C>A p.A700D | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2
- MGAM2 | c.2346C>T p.S782= | Splice Region (SNP) | VAF 24/151 reads (16%) | called by muse, mutect2, varscan2
- MGAT4C | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MICU3 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- MINAR2 | c.547G>C p.V183L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); called by muse, mutect2
- MINDY3 | c.49A>T p.S17C | Missense Mutation (SNP) | VAF 33/432 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); called by muse, mutect2
- MROH2B | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 50/343 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MTREX | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 33/421 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2
- MUC12 | c.15989A>G p.K5330R (on ENST00000379442; = p.K5187R on NM_001164462.1) | Missense Mutation (SNP) | VAF 33/381 reads (9%) | SIFT tolerated (0.06); called by muse, mutect2
- MUSK | c.1814T>C p.M605T | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2
- MYO18A | c.2875C>T p.P959S | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYOZ3 | c.-1G>C | Splice Region (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- NARS2 | c.315G>T p.R105S | Missense Mutation (SNP) | VAF 21/274 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.122); called by muse, mutect2
- NAV3 | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- NCOR2 | c.5040G>T p.E1680D | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NFXL1 | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 30/353 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.318); called by muse, mutect2
- NLRP3 | c.102G>T p.K34N | Missense Mutation (SNP) | VAF 55/487 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- NOTCH3 | c.1775_1792del p.R592_C597del | In Frame Del (DEL) | VAF 22/128 reads (17%) | called by mutect2, pindel, varscan2
- NR0B1 | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.535); called by muse, mutect2
- NR2F2 | c.409A>T p.K137* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | called by muse, mutect2
- NR3C2 | c.2040G>C p.K680N | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.278); called by muse, mutect2
- OPHN1 | c.1140G>T p.M380I | Missense Mutation (SNP) | VAF 53/521 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- OR13G1 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OR4A15 | c.728C>A p.T243N | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- OR5H1 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 23/289 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2
- OR7G1 | c.865A>T p.I289F | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.167); called by muse, mutect2
- OTOF | c.4107G>C p.M1369I (on ENST00000272371 / NM_194248.3; = p.M602I on NM_004802.4) | Missense Mutation (SNP) | VAF 44/388 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTP | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- OTP | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OXR1 | c.874C>A p.Q292K (on ENST00000442977 / NM_001198532.1; = p.Q291K on NM_018002.3) | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARN | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 42/395 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- PCDHA6 | c.1898C>A p.T633N | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PCLO | c.11312A>T p.D3771V | Missense Mutation (SNP) | VAF 29/297 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PCSK2 | c.917G>T p.W306L | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PDZRN4 | c.1025A>G p.H342R (on ENST00000402685 / NM_001164595.2; = p.H84R on NM_013377.4) | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PER2 | c.2243T>A p.I748K | Missense Mutation (SNP) | VAF 62/519 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PITPNM1 | c.2241G>T p.K747N | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.524); called by muse, varscan2
- PKHD1 | c.2591G>T p.R864M | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2
- PLET1 | c.617T>G p.L206R | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PREX1 | c.974A>T p.Y325F | Missense Mutation (SNP) | VAF 37/389 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2
- RAET1E | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 50/578 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.03); called by muse, mutect2
- RASGEF1A | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RIN3 | c.494G>A p.S165N | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); called by muse, mutect2
- ROS1 | c.5126G>T p.G1709V | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RYR3 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RYR3 | c.13016T>C p.V4339A (on ENST00000389232; = p.V4340A on NM_001036.6) | Missense Mutation (SNP) | VAF 68/494 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCN2A | c.3117T>G p.I1039M | Missense Mutation (SNP) | VAF 37/386 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.756); called by muse, mutect2
- SCRT2 | c.716C>A p.P239Q | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCUBE1 | c.420G>T p.E140D | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SESTD1 | c.1174C>G p.Q392E | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.24); called by muse, mutect2
- SH3PXD2B | c.1795G>T p.G599C | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC45A4 | c.1445A>C p.D482A (on ENST00000517878 / NM_001286646.2; = p.D431A on NM_001080431.2) | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.437); called by muse, mutect2
- SLC8A2 | c.370T>A p.W124R | Missense Mutation (SNP) | VAF 58/354 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STK32B | c.145T>C p.Y49H | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SUN3 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.736); called by muse, mutect2
- TBC1D32 | c.874-2A>G p.X292_splice | Splice Site (SNP) | VAF 16/162 reads (10%) | called by muse, mutect2
- TEX51 | c.102G>T p.Q34H | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- TFR2 | c.1282G>T p.V428F | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TIE1 | c.2620+1G>A p.X874_splice | Splice Site (SNP) | VAF 29/358 reads (8%) | called by muse, mutect2
- TMED3 | c.502G>T p.G168* | Nonsense Mutation (SNP) | VAF 25/280 reads (9%) | called by muse, mutect2
- TMEM225 | c.371T>A p.L124Q | Missense Mutation (SNP) | VAF 26/277 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM232 | c.724C>G p.P242A | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMPRSS5 | c.384G>T p.Q128H | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TNKS1BP1 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRAV13-1 | c.150C>A p.N50K | Missense Mutation (SNP) | VAF 27/418 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2
- TRDN | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPC6 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 60/656 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.8774A>C p.E2925A (on ENST00000591111; = p.E2879A on NM_003319.4) | Missense Mutation (SNP) | VAF 46/517 reads (9%) | PolyPhen benign (0.443); called by muse, mutect2
- TTN | c.3970T>C p.W1324R (on ENST00000591111; = p.W1278R on NM_003319.4) | Missense Mutation (SNP) | VAF 20/328 reads (6%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TWNK | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 59/500 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBR4 | c.5566G>T p.D1856Y | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- USP33 | c.2508A>T p.R836S | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- USP33 | c.1888A>T p.S630C | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- WDFY3 | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- WDR37 | c.726+7A>T | Splice Region (SNP) | VAF 38/268 reads (14%) | called by muse, mutect2, varscan2
- WHAMM | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.058); called by muse, mutect2
- WHRN | c.2659G>T p.A887S | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WNK3 | c.2713A>T p.S905C | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WWP1 | c.1226G>T p.W409L | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZAR1L | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ZC3H12B | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 36/348 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZCCHC8 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX4 | c.7171del p.L2391* | Frame Shift Del (DEL) | VAF 38/375 reads (10%) | called by mutect2, pindel
- ZNF208 | c.721T>C p.F241L | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.014); called by muse, mutect2
- ZNF3 | c.775A>G p.S259G | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ZNF653 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 21/142 reads (15%) | called by muse, mutect2, varscan2
- ZNF699 | c.1346G>A p.C449Y | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF862 | c.1072T>A p.Y358N | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- ACSM4 | c.1404C>T p.V468= | Silent (SNP) | VAF 13/289 reads (4%) | catalogued as rs1290852605, COSV68068273; called by muse, mutect2
- AHNAK | c.15390C>T p.H5130= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as rs116380617, COSV99947104; called by muse, mutect2, varscan2
- ANKRD33 | c.408C>A p.P136= (on ENST00000340970 / NM_001304459.2; = p.P261= on NM_182608.4) | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as COSV100001618; called by muse, mutect2, varscan2
- AP002512.3 | c.426G>T p.L142= | Silent (SNP) | VAF 24/406 reads (6%) | catalogued as rs1477687376; called by muse, mutect2
- AR | c.2262C>A p.S754= | Silent (SNP) | VAF 25/384 reads (7%) | called by muse, mutect2
- CAMK2G | c.876C>G p.R292= | Silent (SNP) | VAF 26/246 reads (11%) | called by muse, mutect2
- CDH10 | c.621C>A p.P207= | Silent (SNP) | VAF 14/139 reads (10%) | called by muse, mutect2, varscan2
- CHRD | c.1471C>A p.R491= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99200300; called by muse, mutect2, varscan2
- CHST3 | c.699C>G p.V233= | Silent (SNP) | VAF 24/220 reads (11%) | called by muse, mutect2, varscan2
- CYP2C9 | c.294C>T p.G98= | Silent (SNP) | VAF 65/625 reads (10%) | catalogued as rs1056361080; called by muse, mutect2, varscan2
- DCHS1 | c.3834C>A p.P1278= | Silent (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- DNMBP | c.1830A>T p.P610= | Silent (SNP) | VAF 26/196 reads (13%) | catalogued as COSV60622883; called by muse, mutect2, varscan2
- DPPA3 | c.303C>T p.Y101= | Silent (SNP) | VAF 44/468 reads (9%) | catalogued as rs778144205; called by muse, mutect2
- DYM | c.780C>G p.V260= | Silent (SNP) | VAF 46/366 reads (13%) | called by muse, mutect2, varscan2
- ERBB4 | c.1239C>T p.D413= | Silent (SNP) | VAF 51/442 reads (12%) | called by muse, mutect2, varscan2
- ERICH6B | c.765T>A p.S255= | Silent (SNP) | VAF 50/375 reads (13%) | called by muse, mutect2, varscan2
- ERVFRD-1 | c.777C>A p.G259= | Silent (SNP) | VAF 21/217 reads (10%) | called by muse, mutect2
- FLACC1 | c.756A>G p.E252= | Silent (SNP) | VAF 27/292 reads (9%) | called by muse, mutect2
- FN1 | c.2883T>C p.F961= | Silent (SNP) | VAF 54/528 reads (10%) | catalogued as rs747907753; called by muse, mutect2, varscan2
- FSIP2 | c.16761A>T p.S5587= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as rs1182806592; called by muse, mutect2
- GCNT3 | c.882A>G p.T294= | Silent (SNP) | VAF 23/339 reads (7%) | called by muse, mutect2
- GNPTAB | c.1707A>T p.A569= | Silent (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- GPRIN1 | c.177C>T p.H59= | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- GRIK2 | c.489G>T p.L163= | Silent (SNP) | VAF 35/301 reads (12%) | called by muse, mutect2, varscan2
- H3-5 | c.78C>A p.A26= | Silent (SNP) | VAF 24/177 reads (14%) | called by muse, mutect2, varscan2
- HCN3 | c.1302C>T p.P434= | Silent (SNP) | VAF 28/208 reads (13%) | called by muse, mutect2, varscan2
- ITGAX | c.2211G>C p.T737= | Silent (SNP) | VAF 22/144 reads (15%) | catalogued as COSV51641716, COSV51649751; called by muse, mutect2, varscan2
- KIAA1549 | c.1059A>C p.A353= | Silent (SNP) | VAF 38/282 reads (13%) | catalogued as rs774795805; called by muse, varscan2
- LARGE1 | c.1977G>C p.P659= | Silent (SNP) | VAF 42/409 reads (10%) | catalogued as rs768565081; called by muse, mutect2, varscan2
- LRP2 | c.2172C>T p.F724= | Silent (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- LRP8 | c.2109G>T p.L703= | Silent (SNP) | VAF 24/278 reads (9%) | called by muse, mutect2
- LRRK2 | c.1374G>A p.V458= | Silent (SNP) | VAF 30/375 reads (8%) | called by muse, mutect2
- LTBP4 | c.2097G>T p.P699= (on ENST00000308370 / NM_001042544.1; = p.P662= on NM_003573.2) | Silent (SNP) | VAF 42/358 reads (12%) | called by muse, mutect2, varscan2
- MSI1 | c.748C>A p.R250= | Silent (SNP) | VAF 10/201 reads (5%) | called by muse, mutect2
- MTDH | c.1554C>T p.T518= | Silent (SNP) | VAF 20/198 reads (10%) | catalogued as rs148327274; called by muse, mutect2
- MXRA5 | c.5841G>C p.V1947= | Silent (SNP) | VAF 28/179 reads (16%) | called by muse, mutect2, varscan2
- NCOR2 | c.6999C>G p.A2333= | Silent (SNP) | VAF 25/184 reads (14%) | called by muse, mutect2, varscan2
- NDFIP2 | c.153G>T p.P51= | Silent (SNP) | VAF 30/129 reads (23%) | called by muse, mutect2, varscan2
- NEK1 | c.2709A>G p.L903= | Silent (SNP) | VAF 35/351 reads (10%) | called by muse, mutect2, varscan2
- NISCH | c.4170C>T p.Y1390= | Silent (SNP) | VAF 23/173 reads (13%) | catalogued as rs778934740; called by muse, mutect2, varscan2
- OR2H2 | c.807C>G p.G269= | Silent (SNP) | VAF 24/288 reads (8%) | called by muse, mutect2, varscan2
- OR2T33 | c.576C>T p.V192= | Silent (SNP) | VAF 29/408 reads (7%) | catalogued as COSV100531518, COSV100532223; called by muse, mutect2
- OR6F1 | c.108C>A p.I36= | Silent (SNP) | VAF 39/359 reads (11%) | called by muse, mutect2, varscan2
- OR8G1 | c.552C>T p.L184= | Silent (SNP) | VAF 19/184 reads (10%) | called by muse, mutect2, varscan2
- PCDH10 | c.147G>T p.S49= | Silent (SNP) | VAF 12/169 reads (7%) | called by muse, mutect2
- PCDH15 | c.609C>A p.T203= | Silent (SNP) | VAF 26/276 reads (9%) | catalogued as COSV57277826; called by muse, mutect2
- PDHA1 | c.756G>A p.L252= | Silent (SNP) | VAF 69/461 reads (15%) | catalogued as rs768600287; called by muse, varscan2
- PIEZO1 | c.7458G>C p.L2486= | Silent (SNP) | VAF 35/326 reads (11%) | called by muse, mutect2, varscan2
- PNLIPRP3 | c.1191C>T p.G397= | Silent (SNP) | VAF 8/64 reads (13%) | called by muse, varscan2
- POM121 | c.2172A>T p.A724= (on ENST00000434423; = p.A459= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 94/801 reads (12%) | called by muse, mutect2, varscan2
- PRDM16 | c.2034C>T p.P678= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs371635702; called by muse, varscan2
- PRDM9 | c.1530C>A p.G510= | Silent (SNP) | VAF 58/693 reads (8%) | called by muse, mutect2
- PTPRB | c.312G>A p.V104= | Silent (SNP) | VAF 61/487 reads (13%) | called by muse, mutect2, varscan2
- PXDNL | c.3132C>T p.I1044= | Silent (SNP) | VAF 46/738 reads (6%) | catalogued as rs147708699; called by muse, mutect2
- RAB39B | c.150G>T p.V50= | Silent (SNP) | VAF 45/409 reads (11%) | called by muse, mutect2, varscan2
- RBM20 | c.1212T>A p.G404= | Silent (SNP) | VAF 54/556 reads (10%) | called by muse, mutect2
- REG3A | c.267C>A p.S89= | Silent (SNP) | VAF 16/295 reads (5%) | called by muse, mutect2
- RNF168 | c.1185T>C p.F395= | Silent (SNP) | VAF 24/258 reads (9%) | called by muse, mutect2
- RPRD2 | c.231C>G p.L77= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as rs1560184977, COSV100954728, COSV64816720; called by muse, mutect2, varscan2
- RTL3 | c.1137C>A p.A379= | Silent (SNP) | VAF 46/574 reads (8%) | catalogued as COSV58185369; called by muse, mutect2
- RTTN | c.1854G>A p.V618= | Silent (SNP) | VAF 24/360 reads (7%) | called by muse, mutect2
- SCN10A | c.459A>G p.P153= | Silent (SNP) | VAF 38/277 reads (14%) | called by muse, mutect2, varscan2
- SH3GL3 | c.801C>G p.L267= | Silent (SNP) | VAF 32/389 reads (8%) | catalogued as COSV61063442; called by muse, mutect2
- SIN3A | c.1794G>A p.V598= | Silent (SNP) | VAF 20/259 reads (8%) | called by muse, mutect2
- SLC24A3 | c.1005C>A p.T335= | Silent (SNP) | VAF 24/281 reads (9%) | called by muse, mutect2
- SLC9A3 | c.1782C>G p.V594= | Silent (SNP) | VAF 15/135 reads (11%) | called by muse, mutect2, varscan2
- SMTNL1 | c.1029C>A p.V343= (on ENST00000399154; = p.V380= on NM_001105565.2) | Silent (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- SPRY3 | c.807G>T p.V269= | Silent (SNP) | VAF 25/166 reads (15%) | catalogued as COSV100249267; called by muse, mutect2, varscan2
- STARD8 | c.765G>T p.R255= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as rs1173649543; called by muse, mutect2
- TAS2R20 | c.330C>A p.I110= | Silent (SNP) | VAF 16/241 reads (7%) | catalogued as rs1392922214, COSV67862279; called by muse, mutect2
- TAS2R42 | c.528T>C p.D176= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs780712099; called by muse, mutect2
- TBC1D15 | c.1923C>T p.D641= | Silent (SNP) | VAF 56/378 reads (15%) | catalogued as rs778073078; called by muse, mutect2, varscan2
- TDRD9 | c.2385C>G p.L795= | Silent (SNP) | VAF 11/127 reads (9%) | called by muse, mutect2
- TMC6 | c.1335G>T p.A445= | Silent (SNP) | VAF 29/267 reads (11%) | called by muse, mutect2, varscan2
- TMEM132C | c.816C>A p.V272= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as COSV70658509; called by muse, mutect2, varscan2
- TOX | c.1314G>A p.P438= | Silent (SNP) | VAF 24/167 reads (14%) | catalogued as rs369635293; called by muse, mutect2, varscan2
- TRAV18 | c.36G>A p.L12= | Silent (SNP) | VAF 28/294 reads (10%) | called by muse, mutect2, varscan2
- TTC21B | c.817T>C p.L273= | Silent (SNP) | VAF 20/474 reads (4%) | called by muse, mutect2
- TTLL4 | c.324C>G p.L108= | Silent (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- TTN | c.35904A>G p.P11968= (on ENST00000591111; = p.P4544= on NM_003319.4) | Silent (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- UNC5C | c.2034T>C p.A678= | Silent (SNP) | VAF 27/477 reads (6%) | called by muse, mutect2
- UNC80 | c.9699G>A p.P3233= | Silent (SNP) | VAF 47/423 reads (11%) | catalogued as rs1404826380; called by muse, mutect2, varscan2
- ZBTB20 | c.462C>A p.L154= (on ENST00000474710 / NM_001164342.2; = p.L81= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 30/392 reads (8%) | called by muse, mutect2
- ZNF804B | c.1797G>A p.E599= | Silent (SNP) | VAF 20/292 reads (7%) | catalogued as COSV60826129; called by muse, mutect2
- AC244394.2 | n.1161G>T | RNA (SNP) | VAF 24/272 reads (9%) | called by muse, mutect2
- ACSL6 | c.-23C>A | 5'UTR (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- ADGRL4 | c.*27C>A | 3'UTR (SNP) | VAF 18/106 reads (17%) | catalogued as COSV100876578; called by muse, mutect2, varscan2
- AGAP14P | n.1244T>A | RNA (SNP) | VAF 67/784 reads (9%) | called by muse, mutect2, varscan2
- AMH | c.555+33C>T | Intron (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- ARHGAP9 | c.-25C>G | 5'UTR (SNP) | VAF 15/205 reads (7%) | called by muse, mutect2
- ARMCX4 | c.1038+1568A>G | Intron (SNP) | VAF 34/289 reads (12%) | catalogued as rs1556008693; called by muse, mutect2, varscan2
- BMERB1 | chr16:15591091 G>C | 3'Flank (SNP) | VAF 35/428 reads (8%) | catalogued as rs761378684; called by muse, mutect2
- C1orf174 | c.-29C>T | 5'UTR (SNP) | VAF 9/67 reads (13%) | catalogued as rs375734586; called by muse, mutect2, varscan2
- CCDC57 | c.2241+6016G>C | Intron (SNP) | VAF 19/155 reads (12%) | called by muse, mutect2, varscan2
- CHCHD5 | c.*15del | 3'UTR (DEL) | VAF 24/217 reads (11%) | catalogued as COSV61424724; called by mutect2, pindel, varscan2
- CHIA | c.480+386C>T | Intron (SNP) | VAF 21/317 reads (7%) | called by muse, mutect2
- COL11A1 | c.780+41G>C | Intron (SNP) | VAF 24/288 reads (8%) | catalogued as rs777913738; called by muse, mutect2
- DDHD2 | c.622+33G>T | Intron (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- DOCK3 | c.163-12550A>G | Intron (SNP) | VAF 20/183 reads (11%) | called by muse, mutect2, varscan2
- ENAH | c.803-79C>G | Intron (SNP) | VAF 30/233 reads (13%) | called by muse, mutect2, varscan2
- FAP | c.414-1778G>T | Intron (SNP) | VAF 33/453 reads (7%) | called by muse, mutect2
- HSP90AA4P | n.1519G>T | RNA (SNP) | VAF 12/217 reads (6%) | called by muse, mutect2
- LINC00840 | n.354C>A | RNA (SNP) | VAF 40/490 reads (8%) | called by muse, mutect2
- LINC01548 | n.510A>G | RNA (SNP) | VAF 27/304 reads (9%) | called by muse, mutect2
- LINC02649 | n.431C>T | RNA (SNP) | VAF 19/187 reads (10%) | catalogued as rs912275245; called by muse, mutect2, varscan2
- MIR6511A1 | chr16:14929405 G>A | 3'Flank (SNP) | VAF 20/266 reads (8%) | catalogued as rs745603026; called by muse, mutect2
- MRGPRG | chr11:3222051 C>T | 5'Flank (SNP) | VAF 27/200 reads (14%) | catalogued as rs755465139; called by muse, mutect2, varscan2
- MRTFA | c.601+108G>T | Intron (SNP) | VAF 32/242 reads (13%) | called by muse, mutect2, varscan2
- MSX1 | c.470-229G>T | Intron (SNP) | VAF 13/95 reads (14%) | catalogued as rs1328806991; called by muse, mutect2, varscan2
- MYADML | n.686C>A | RNA (SNP) | VAF 27/205 reads (13%) | called by muse, mutect2, varscan2
- MYH2 | c.204+44T>C | Intron (SNP) | VAF 76/631 reads (12%) | called by muse, mutect2, varscan2
- NANOGP1 | n.502T>A | RNA (SNP) | VAF 40/402 reads (10%) | called by muse, mutect2
- NIN | chr14:50723638 T>G | 3'Flank (SNP) | VAF 36/378 reads (10%) | called by muse, mutect2
- PHLDB2 | c.1335+44C>T | Intron (SNP) | VAF 20/289 reads (7%) | called by muse, mutect2
- PLOD2 | c.1501-986A>G | Intron (SNP) | VAF 42/341 reads (12%) | called by muse, mutect2, varscan2
- REXO1L1P | n.1432C>T | RNA (SNP) | VAF 30/1304 reads (2%) | called by muse, mutect2
- SCML4 | c.157-5816A>T | Intron (SNP) | VAF 11/177 reads (6%) | called by muse, mutect2
- SKA2P1 | n.46C>T | RNA (SNP) | VAF 30/312 reads (10%) | called by muse, mutect2, varscan2
- SLC12A1 | c.1215+82T>A | Intron (SNP) | VAF 33/292 reads (11%) | called by muse, mutect2, varscan2
- SRPK1 | c.75-13936G>T | Intron (SNP) | VAF 19/253 reads (8%) | called by muse, mutect2
- TNIP3 | c.946+657C>A | Intron (SNP) | VAF 17/388 reads (4%) | called by muse, mutect2
- TTC21A | c.268+15G>T | Intron (SNP) | VAF 51/429 reads (12%) | catalogued as rs755482726; called by muse, mutect2, varscan2
- TTN | c.41773+9C>A | Intron (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- USP32 | c.-2G>T | 5'UTR (SNP) | VAF 17/151 reads (11%) | called by muse, mutect2, varscan2
- VEGFC | c.-12G>A | 5'UTR (SNP) | VAF 6/54 reads (11%) | called by mutect2, varscan2
